Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IO, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IO-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. SPLEEN AND PANCREAS, RESECTION:
Pancreatic endocrine neoplasm, well differentiated.
Tumor size: 3 cm.
Mitotic count: about 1 per 10 HPF.
No necrosis is present.
Pancreatic margin of resection is free of tumor.
A focus of PanIN 1-2 present at the pancreatic resection margin.
Uninvolved pancreatic parenchyma with focal fibrosis, atrophy and PanIN-3.
Spleen with no significant pathologic findings.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by

Comment

This case (slide FSA2) was reviewed prospectively at the slide review conference.

Ancillary Studies

Immunohistochemistry stain, performed with proper control, revealed the tumor cells to be positive for Synaptophysin and chromogranin and CD56.
Ki-67 immunostain, performed with the proper control on block A4, showed proliferation index approximately less than 1% (manual count).

Specimen(s) Received

A SPLEEN AND PANCREAS 3 FS

Clinical History

PANCREATIC NEUROENDOCRINE TUMOR

Preoperative Diagnosis

NONE GIVEN

Frozen Section Diagnosis

FSA1-FSA2. PANCREATIC MARGIN:
No invasive tumor present.

ICDO 3
Carcinoma, neuroendocrine NOS
Site: ^{CICE} Pancreas body 824613
^{path} Pancreas NOS 825.1
JAS 4/16/14

[page 2 of 2]
FSA3. Carcinoma with endocrine features.

These frozen section diagnoses/results were communicated to and acknowledged by

I, M.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh for OR consult labeled "spleen and pancreas (check margin), frozen section". The specimen consists of a resected portion of the pancreas with adjacent spleen (14.5 x 9.0 x 7.0 cm). The pancreas measures 6.5 x 4.0 x 2.5 cm). A palpable mass is grossly appreciated. The overlying tissue is marked with blue ink. Serial sections reveal a partially calcified brown-tan ill-defined mass (3.0 x 2.0 x 2.0). The mass is located 4.0 cm from the pancreatic surgical margin of resection abutting the overlying soft tissue. A portion of the tumor is taken and submitted for frozen section as FSA3. The pancreatic margin is removed tangentially and entirely submitted for frozen sections FSA1 and FSA2. The pancreatic duct is patent and grossly free of tumor. The remaining pancreatic parenchyma is grossly unremarkable. The attached spleen measures 11.5 x 6.5 x 5.5 cm. The capsule is red brown and intact. Cut surface exhibits a grossly unremarkable spleen parenchyma. Adjacent to the tissue is a moderate amount of fat (25.0 x 9.0 x 2.0 cm). A representative section of the tumor is submitted to the Tissue Procurement Laboratory. Permanent representative sections are submitted following decalcification as:

- A4: Mirror image of tumor submitted to Tissue Procurement Laboratory
- A5-A9: Random representative sections of calcified mass
- A10: Grossly unremarkable pancreas
- A11: Grossly unremarkable spleen
- A12: Pancreas showing relationship to spleen
- A13-A17: Adipose tissue adjacent to lesion
- A18-A22: Additional sections from pancreas

Source: NCI Genomic Data Commons file cda17c43-3214-459b-a4ef-1ffa4a674bb3 (TCGA-3A-A9IO.4151276B-536F-47F2-9B97-92E79722AB68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).